Surgical pathology report (de-identified scan), TCGA case TCGA-DK-A3IL, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DK-A3IL-01A (Primary Tumor).

[page 1 of 4]
SURGICAL PATHOLOGY REPORT

Patient Name:

Med. Rec. #:

DOB: (Age:

Gender: F

Ref. Physician:

Patient Address:

Location:

Service: Urology

Accession #:

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Billing Type: INPATIENT

Additional Copy to:

Ref. Source:

Clinical Diagnosis & History:

Bladder carcinoma, T2.

Specimens Submitted:

- 1: Right distal pelvic lymph nodes
- 2: Left distal pelvic lymph nodes
- 3: Bladder, uterus, fallopian tubes and ovary, inter vaginal wall, perivesicle tissue
- 4: Right ureteral stent
- 5: Left distal ureter
- 6: Right distal ureter

DIAGNOSIS:

1. Right distal pelvic lymph nodes:

Part # 1

Lymph Node Dissection:

Metastatic urothelial carcinoma

Number of lymph nodes examined: 3

Number of lymph nodes with metastatic disease: 2

Size of the largest lymph node involved by tumor: 1.2cm.

Size of the largest metastatic focus : 1.2 cm.

Extranodal extension is not identified

100-0-3

carcinoma, urothelial, NOS 8/20/3

2. Left distal pelvic lymph nodes:

Part # 2

Lymph Node Dissection:

Benign lymph nodes

Number of lymph nodes examined: 1

Path Site: bladder, NOS C67.9

CQC: bladder, wall, lateral C67.2

bw
12/7/11

3. Bladder, uterus, fallopian tubes and ovary, inter vaginal wall, perivesicle tissue:

Part # 3

Tumor Type:

Invasive urothelial carcinoma, NOS

Histologic Grade:

High grade

Pattern of growth of the Non-Invasive component:

Flat (in situ carcinoma)

Pattern of growth of the Invasive component:

Infiltrating

Tumor Multicentricity:

Identified

[page 2 of 4]
SURGICAL PATHOLOGY REPORT

Bladder Local Invasion:

Perivesical soft tissues

Extravesical Tumor Extension:

Ureters uninvolved

Urethra uninvolved

Vascular Invasion:

Identified

Perineural Invasion:

Not identified

Surgical Margins:

Free of tumor

Non-Neoplastic Mucosa:

Exhibiting ulceration

Exhibiting foreign body reaction

Female Genital Organs:

The right ovary shows stromal hyperplasia

The left ovary shows stromal hyperplasia

Remaining genital organs are unremarkable

Perivesical Lymph Nodes:

Not involved 0/1

The Pathologic Stage is (AJCC 2002):

pT3 (Invasion of perivesicle soft tissue)

4. Right ureteral stent:

- Gross diagnosis only.

5. Left distal ureter; excision:

- Segment of benign ureter.

6. Right distal ureter; excision:

- Segment of ureter with mild to moderate urothelial atypia; no carcinoma is identified.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

1). The specimen is received fresh, labeled "Right distal pelvic lymph nodes" and consists of three pink tan firm lymph nodes ranging from 1.5 x 0.8 cm up to 6 x 2.5 cm in greatest dimension. Half of the two smaller lymph nodes are submitted to TPS. All remaining identified lymph nodes are submitted.

Summary of sections:

RLN -remaining halves of two smaller lymph nodes

LLN - largest lymph node

2). The specimen is received fresh, labeled "Left pelvic lymph nodes " and consists of a single lymph node measuring 5.5 x 2 x 0.8 cm. The lymph node is entirely submitted.

Summary of sections:

LN - lymph node

[page 3 of 4]
SURGICAL PATHOLOGY REPORT

3). The specimen is received fresh, labeled "bladder, uterus, fallopian tubes and ovaries, vagina wall, perivesical tissue". It consists of a 7 x 5 x 3 cm bladder with attached uterus in continuity with the cervix (6.8 X 3.3 x 2.4 cm), right ovary (1.8 x 1.3 x 0.6), left ovary (1.7 x 1.2 x 0.6cm), right fallopian tube (4.3 cm in length x 0.5 cm in average diameter) and left fallopian tube (4.7 cm in length x 0.5 cm in average diameter) and vaginal cuff (3.6 x 2.1 x 0.5 cm). The distal urethra and the vaginal cuff margin are shaved and submitted. The ureteric stumps measure 0.8 (right) and 0.2 (left) cm in length. The left is inked blue and the right is inked green. The bladder is opened anteriorly to reveal an ulcerated firm lesion measuring 3.3 x 3 cm. The lesion is located in the right lateral wall, right posterior wall, right trigone. It extends to the right urethra but does not extend to the margin. The right ureteral orifice is located within the lesion. The left ureteric orifice is located 0.9 cm from the lesion. On sectioning, the tumor extends 0.8 cm to the perivesical fat but not to the inked surface. The remaining bladder mucosa is unremarkable. The uterus, ovaries and fallopian tubes are unremarkable. Tissue is submitted for Representative sections are submitted.

Summary of sections:

UTHM - distal urethra

RUM - right ureter margin

LUM - left ureter margin

L - lesion

LM - lesion and adjacent mucosa

RUO - right ureteric orifice

LUO - left ureteric orifice

LP- left posterior wall

LA - left anterior wall

RP- right posterior wall

RA - right anterior wall

TRI - trigone

DOVE - dome

EMM - endomyometrium

CX - cervix

DVM - distal vaginal margin

RTO - right tube and ovary

LTO - left tube and ovary

4). The specimen is received fresh labeled, "Right ureteral stent" and consists of an elongated tubular blue stent measuring 25 x 0.2 cm. The specimen is photographed. Gross only.

5). The specimen is received in formalin labeled "Left distal ureter, unclipped mark is the margin." It consists of a segment of ureter measuring 2.7 cm in length and 0.6 cm in diameter. There is a clip on one end of the specimen. The specimen is serially sectioned from the tip with the clip to the non-clipped end and submitted entirely.

Summary of sections:

TC-tip with clip

SS-serial sections from clipped to non-clipped end

TWC-Tip without clip

6). The specimen is received in formalin labeled "Right distal ureter, unclipped mark is the margin." It consists of a segment of ureter measuring 2.4 cm in length and 0.6 cm in diameter. There is a clip on one end of the specimen. The specimen is serially sectioned from the tip with the clip to the non-clipped end and submitted entirely.

Summary of sections:

TC-tip with clip

SS-serial sections from clipped to non-clipped end

TWC-Tip without clip

Summary of Sections:

Part 1: Right distal pelvic lymph nodes

[page 4 of 4]
SURGICAL PATHOLOGY REPORT

Block	Sect. Site	PCs
5	LLN	5
1	RLN	1

Part 2: Left distal pelvic lymph nodes

Block	Sect. Site	PCs
5	LN	5

Part 3: Bladder, uterus, fallopian tubes and ovary, inter vaginal wall, perivesicle tissue

Block	Sect. Site	PCs
1	CX	1
1	DOM	1
1	DVM	1
1	EMM	1
3	L	3
1	LA	1
2	LM	2
1	LN	5
1	LP	1
1	LTO	1
1	LUM	1
1	LUO	1
1	RA	1
1	RP	1
1	RTO	1
1	RUM	1
1	RUO	1
1	TRI	1
1	UTHM	1

Part 4: Right ureteral stent**Part 5: Left distal ureter**

Block	Sect. Site	PCs
1	SS	1
1	tc	1
1	twc	1

Part 6: Right distal ureter

Block	Sect. Site	PCs
1	SS	1
1	tc	1
1	twc	1

Source: NCI Genomic Data Commons file 4a0398fd-89e7-4720-a73d-46c606a42550 (TCGA-DK-A3IL.FE31B934-2AE5-4CA6-981D-DF7C0F9E1677.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).